Somatic mutation profile of tumor specimen TCGA-XR-A8TE-01A (aliquot TCGA-XR-A8TE-01A-11D-A35Z-10) from TCGA case TCGA-XR-A8TE, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 16.0 years (5,862 days).
Specimen TCGA-XR-A8TE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 113b1ec4-aa80-44f3-ba74-254875f54348.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XR-A8TE-10A (Blood Derived Normal), aliquot TCGA-XR-A8TE-10A-01D-A35Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/34514909-0be5-4150-845e-a3a5038c5687

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 9, Silent 6, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLIP4 | c.668C>A p.P223H | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100192066; called by muse, mutect2, varscan2
- FLVCR1 | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100875083; called by muse, mutect2
- KLRC1 | c.188-1G>T p.X63_splice | Splice Site (SNP) | VAF 14/64 reads (22%) | catalogued as COSV100760840; called by muse, mutect2, varscan2
- KMT2C | c.2370C>A p.D790E | Missense Mutation (SNP) | VAF 16/320 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV100073648; called by muse, mutect2
- LRRC4 | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.45); catalogued as COSV50813193, COSV99975093; called by muse, mutect2, varscan2
- MBD3L1 | c.505G>A p.A169T | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as rs761880439, COSV59775939; called by muse, mutect2, varscan2
- MUC15 | c.992G>A p.R331H | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.291); catalogued as rs560016592, COSV55553303; called by muse, mutect2, varscan2
- SIX2 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1164647831, COSV57391622; called by muse, mutect2
- WNK4 | c.314C>A p.P105H | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV99519490; called by muse, mutect2, varscan2
- XKR4 | c.910A>C p.M304L | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as COSV100533080; called by muse, mutect2, varscan2
- SYT7 | c.1063del p.V355Sfs*27 | Frame Shift Del (DEL) | VAF 21/75 reads (28%) | called by mutect2, pindel, varscan2
- AHR | c.306A>G p.R102= | Silent (SNP) | VAF 30/638 reads (5%) | catalogued as COSV54122523, COSV99619882; called by muse, mutect2
- GNA14 | c.138T>C p.S46= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100503165; called by muse, mutect2, varscan2
- GPM6A | c.732C>T p.D244= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs141777363; called by muse, mutect2, varscan2
- HEXD | c.372G>A p.A124= | Silent (SNP) | VAF 50/151 reads (33%) | catalogued as rs552127805, COSV100027812; called by muse, mutect2, varscan2
- MMRN1 | c.2967G>A p.S989= | Silent (SNP) | VAF 32/165 reads (19%) | catalogued as rs762745325, COSV53333481; called by muse, mutect2, varscan2
- MUC5B | c.6276C>A p.P2092= | Silent (SNP) | VAF 12/134 reads (9%) | catalogued as COSV101500503; called by muse, mutect2
